Somatic mutation profile of tumor specimen 96c52a27-3d9a-49e7-8ae8-a71e7c (aliquot 96c52a27-3d9a-49e7-8ae8-a71e7c_D6_1) from CPTAC case 01BR031, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 61.0 years (22,264 days).
Specimen 96c52a27-3d9a-49e7-8ae8-a71e7c: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c32e0458-05bc-4d3f-af06-228fae67a340.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 107c4d84-cd05-487c-a3aa-bbe849 (Blood Derived Normal), aliquot 107c4d84-cd05-487c-a3aa-bbe849_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6409d846-0a37-47d8-9088-32cefd591eab

The open-access MAF lists 77 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 14, Intron 8, Frame Shift Del 4, 3'UTR 3, Nonsense Mutation 2, In Frame Del 2, 5'Flank 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 316/490 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP63 | c.1780C>T p.R594* | Nonsense Mutation (SNP) | VAF 113/382 reads (30%) | catalogued as rs900140738, COSV53196111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.16891A>G p.R5631G | Missense Mutation (SNP) | VAF 97/181 reads (54%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs779897817; called by muse, mutect2, varscan2
- FAT3 | c.6731G>A p.S2244N | Missense Mutation (SNP) | VAF 108/323 reads (33%) | SIFT tolerated (0.98); PolyPhen benign (0.327); catalogued as COSV53183865; called by muse, mutect2, varscan2
- FCRL5 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 84/411 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.18); catalogued as rs1479904296; called by muse, mutect2, varscan2
- N4BP2L2 | c.1203G>T p.Q401H | Missense Mutation (SNP) | VAF 70/127 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1174483220; called by muse, mutect2, varscan2
- OR10Q1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 131/457 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.028); catalogued as rs200434876; called by muse, mutect2, varscan2
- PIK3CB | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 16/80 reads (20%) | catalogued as rs1331108652, COSV56691873; called by muse, mutect2, varscan2
- SNTG1 | c.1043G>C p.S348T | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.079); catalogued as COSV99385485; called by muse, mutect2, varscan2
- STAT3 | c.1889-2A>C p.X630_splice | Splice Site (SNP) | VAF 156/328 reads (48%) | catalogued as COSV52890065; called by muse, mutect2, varscan2
- TPBG | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.46); catalogued as rs1241381878; called by muse, mutect2, varscan2
- ZNF100 | c.1219G>T p.G407C | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV99974256; called by mutect2, varscan2
- ZNF431 | c.1385G>A p.G462D | Missense Mutation (SNP) | VAF 79/241 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as rs1217396089; called by muse, mutect2, varscan2
- BAZ2B | c.1507C>A p.Q503K | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- BRD7 | c.1030A>C p.K344Q | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- BRWD3 | c.2746G>T p.G916C | Missense Mutation (SNP) | VAF 85/203 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CLCN2 | c.1924C>G p.P642A | Missense Mutation (SNP) | VAF 168/548 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL6A6 | c.6333G>C p.Q2111H | Missense Mutation (SNP) | VAF 110/247 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DACT2 | c.919A>T p.S307C | Missense Mutation (SNP) | VAF 111/229 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- DGCR6L | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 155/267 reads (58%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EIF4G1 | c.909C>G p.I303M (on ENST00000346169 / NM_198241.3; = p.I107M on NM_004953.5) | Missense Mutation (SNP) | VAF 85/332 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ENY2 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 39/132 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- EPS15L1 | c.2725G>A p.A909T | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- FH | c.229A>C p.M77L | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- FOXK2 | c.1187A>G p.E396G | Missense Mutation (SNP) | VAF 69/149 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GPR141 | c.764_767delinsT p.S255_N256delinsF | In Frame Del (DEL) | VAF 58/141 reads (41%) | called by pindel, varscan2*
- HFM1 | c.3581G>C p.R1194P | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAP3K1 | c.2289_2336del p.R763_T779delinsS | In Frame Del (DEL) | VAF 47/200 reads (24%) | called by mutect2, pindel, varscan2
- MAPKAPK3 | c.628G>C p.A210P | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAST3 | c.3166A>G p.M1056V | Missense Mutation (SNP) | VAF 50/159 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- MST1 | c.2112G>C p.W704C | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- MUC20 | c.333G>C p.E111D | Missense Mutation (SNP) | VAF 124/718 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- NAV3 | c.3874_3880del p.S1292Vfs*11 | Frame Shift Del (DEL) | VAF 115/431 reads (27%) | called by mutect2, pindel, varscan2
- NEB | c.14909T>G p.F4970C | Missense Mutation (SNP) | VAF 77/140 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEIL3 | c.1265C>G p.A422G | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2
- PKHD1L1 | c.2729T>A p.V910D | Missense Mutation (SNP) | VAF 41/92 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHA5 | c.2497G>A p.E833K | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- PPP3CB | c.859A>C p.I287L | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- RBMX | c.461C>A p.P154Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- RPL7 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RRAGC | c.791T>A p.V264D | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- RTL9 | c.3884G>C p.G1295A | Missense Mutation (SNP) | VAF 99/315 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- SETD6 | c.25C>A p.R9= | Splice Region (SNP) | VAF 35/71 reads (49%) | called by muse, mutect2, varscan2
- SLC25A13 | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 82/310 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- TOB2 | c.988del p.M330Cfs*88 | Frame Shift Del (DEL) | VAF 26/61 reads (43%) | called by mutect2, pindel, varscan2
- TRAPPC4 | c.2_38del p.M1_?13 | Frame Shift Del (DEL) | VAF 63/217 reads (29%) | called by mutect2, pindel, varscan2
- UNC79 | c.7148C>G p.A2383G (on ENST00000393151 / NM_001346218.2; = p.A2206G on NM_020818.5) | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- USF1 | c.929A>G p.N310S | Missense Mutation (SNP) | VAF 42/196 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZAN | c.6691C>G p.L2231V | Missense Mutation (SNP) | VAF 75/352 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- ZNF710 | c.1292del p.G431Afs*58 | Frame Shift Del (DEL) | VAF 56/280 reads (20%) | called by mutect2, varscan2
- ASB17 | c.477G>A p.Q159= | Silent (SNP) | VAF 64/131 reads (49%) | catalogued as rs1225524062; called by muse, mutect2, varscan2
- COL18A1 | c.4473G>T p.R1491= (on ENST00000359759 / NM_130444.3; = p.R1256= on NM_030582.4) | Silent (SNP) | VAF 91/309 reads (29%) | called by muse, mutect2, varscan2
- FOXP3 | c.255G>C p.R85= | Silent (SNP) | VAF 121/220 reads (55%) | called by muse, mutect2, varscan2
- MAGEL2 | c.2634G>A p.P878= | Silent (SNP) | VAF 115/514 reads (22%) | catalogued as rs757335294, COSV58565887; called by muse, mutect2, varscan2
- MC5R | c.684G>A p.A228= | Silent (SNP) | VAF 77/283 reads (27%) | catalogued as COSV61253842; called by muse, mutect2, varscan2
- PABPC1L | c.1809C>T p.A603= | Silent (SNP) | VAF 67/131 reads (51%) | catalogued as rs569467865; called by muse, mutect2, varscan2
- SLC22A3 | c.546C>T p.I182= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as rs762009392, COSV99279460; called by muse, mutect2, varscan2
- STON2 | c.2184G>T p.R728= (on ENST00000649389 / NM_001366849.2; = p.R671= on NM_001256430.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 90/182 reads (49%) | called by muse, mutect2, varscan2
- TP53 | c.816G>T p.V272= | Silent (SNP) | VAF 296/459 reads (64%) | catalogued as COSV52918960, COSV53313340, COSV53438396; called by mutect2, varscan2
- TRIM39 | c.18G>C p.L6= | Silent (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- TSKU | c.678G>A p.A226= | Silent (SNP) | VAF 169/509 reads (33%) | catalogued as rs772104778, COSV60751678; called by muse, mutect2, varscan2
- ZFC3H1 | c.3093T>G p.V1031= | Silent (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- ZNF169 | c.1497G>A p.S499= | Silent (SNP) | VAF 163/338 reads (48%) | catalogued as rs1307992517, COSV61763938, COSV61767381; called by mutect2, varscan2
- ZNF469 | c.4371C>T p.A1457= (on ENST00000437464; = p.A1485= on NM_001367624.2) | Silent (SNP) | VAF 257/660 reads (39%) | catalogued as rs375783673; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498989 T>C | 5'Flank (SNP) | VAF 41/103 reads (40%) | catalogued as rs754397792; called by muse, mutect2, varscan2
- BHLHE41 | c.*8C>A | 3'UTR (SNP) | VAF 638/770 reads (83%) | catalogued as rs1460650265; called by muse, mutect2, varscan2
- CYLC2 | chr9:102995331 C>A | 5'Flank (SNP) | VAF 10/18 reads (56%) | catalogued as rs369916189; called by muse, mutect2, varscan2
- DNAH7 | c.1353+1529C>A | Intron (SNP) | VAF 37/67 reads (55%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.1836+29888G>T | Intron (SNP) | VAF 20/80 reads (25%) | catalogued as rs770220964; called by muse, mutect2, varscan2
- JAML | c.772+398G>A | Intron (SNP) | VAF 60/232 reads (26%) | called by muse, mutect2, varscan2
- MASP1 | c.1304-5222A>C | Intron (SNP) | VAF 15/414 reads (4%) | called by muse, mutect2
- PIK3CB | c.2942+46T>C | Intron (SNP) | VAF 11/35 reads (31%) | called by muse, mutect2, varscan2
- PPP2R2C | c.71-82G>A | Intron (SNP) | VAF 140/309 reads (45%) | catalogued as rs757029398; called by muse, mutect2, varscan2
- PRKRA | c.318-13A>T | Intron (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- ROBO1 | c.1343-20C>T | Intron (SNP) | VAF 41/85 reads (48%) | called by muse, mutect2, varscan2
- TMCO1 | c.*2260T>A | 3'UTR (SNP) | VAF 95/267 reads (36%) | called by muse, mutect2, varscan2
- TMCO1 | c.*1040A>C | 3'UTR (SNP) | VAF 66/214 reads (31%) | called by muse, mutect2, varscan2
